Somatic mutation profile of tumor specimen TCGA-ZJ-AAX8-01A (aliquot TCGA-ZJ-AAX8-01A-11D-A42O-09) from TCGA case TCGA-ZJ-AAX8, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 58.8 years (21,481 days).
Specimen TCGA-ZJ-AAX8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6cfc5817-594b-4210-9a90-866d545bc2c0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZJ-AAX8-10A (Blood Derived Normal), aliquot TCGA-ZJ-AAX8-10A-01D-A42R-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e9bab81d-db1a-4bb0-8488-113dda21c331

The open-access MAF lists 72 somatic variants for this specimen: 52 protein-altering or splice-affecting, 19 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 19, Nonsense Mutation 4, Frame Shift Del 1, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 79/170 reads (46%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABHD13 | c.325G>A p.D109N | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV101024215; called by muse, mutect2
- AHRR | c.385G>C p.E129Q | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV100327682; called by muse, mutect2, varscan2
- AIFM3 | c.1070C>T p.S357F | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV59002593; called by muse, mutect2
- ATAD2 | c.2396G>C p.G799A | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99784981; called by muse, mutect2, varscan2
- BCORL1 | c.4030G>A p.E1344K | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs1216044383, COSV99500150; called by muse, mutect2, varscan2
- CD22 | c.1037G>A p.G346E | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as COSV50060831; called by muse, mutect2, varscan2
- CDH23 | c.4628G>A p.G1543E | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.99); catalogued as COSV99822276; called by muse, mutect2, varscan2
- CFTR | c.4235A>G p.Q1412R | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99137706; called by mutect2, varscan2
- CLDN4 | c.488C>A p.S163* | Nonsense Mutation (SNP) | VAF 5/30 reads (17%) | catalogued as COSV52896949, COSV99936548; called by muse, mutect2, varscan2
- CLOCK | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100011884; called by muse, mutect2, varscan2
- CSPP1 | c.3721G>C p.E1241Q (on ENST00000676605; = p.E1200Q on NM_024790.6) | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.449); catalogued as rs201972175, COSV99139068; called by muse, mutect2, varscan2
- CTSK | c.674G>A p.R225K | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV99648858; called by muse, varscan2
- DAAM1 | c.1051G>C p.E351Q | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.404); catalogued as COSV62837620; called by muse, mutect2
- DEPDC1 | c.1865G>A p.R622H (on ENST00000456315 / NM_001114120.3; = p.R338H on NM_017779.6) | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs148919381; called by muse, mutect2, varscan2
- DLAT | c.1487C>T p.S496F | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99734838; called by muse, mutect2, varscan2
- EFCAB13 | c.1324C>G p.L442V | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.089); catalogued as COSV100516421, COSV100516744; called by muse, mutect2, varscan2
- FKBP4 | c.976G>T p.A326S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.59); catalogued as COSV99133858; called by mutect2, varscan2
- GALM | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1440213702, COSV99697296; called by muse, mutect2, varscan2
- GNAS | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as COSV100007076; called by muse, mutect2, varscan2
- GPR158 | c.789C>G p.F263L | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100893968; called by muse, mutect2
- GPRASP1 | c.377C>G p.S126C | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.935); catalogued as COSV100851032, COSV64356441; called by muse, mutect2, varscan2
- HK1 | c.2359C>T p.L787F | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100067204; called by muse, mutect2, varscan2
- ICAM1 | c.1403G>A p.R468H | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.978); catalogued as rs200230807, COSV53425163; called by mutect2, varscan2
- ITPKC | c.1987G>T p.E663* | Nonsense Mutation (SNP) | VAF 5/29 reads (17%) | catalogued as COSV54574303, COSV99648935; called by muse, mutect2
- KMT2D | c.15340C>T p.H5114Y | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56429389; called by muse, mutect2, varscan2
- MKI67 | c.7981C>A p.P2661T | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.73); PolyPhen benign (0.031); catalogued as COSV100896778; called by muse, mutect2, varscan2
- MKI67 | c.3791G>T p.S1264I | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100896779; called by muse, mutect2, varscan2
- MYO7B | c.3857G>A p.R1286Q | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs375117051; called by muse, mutect2
- NALCN | c.2443G>C p.A815P | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99216381; called by muse, mutect2, varscan2
- PARM1 | c.314C>T p.S105L | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.04); catalogued as rs1394712336, COSV56653477; called by muse, mutect2, varscan2
- PBRM1 | c.3853G>A p.D1285N (on ENST00000296302 / NM_001366071.2; = p.D1260N on NM_018313.5) | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.631); catalogued as COSV99969814; called by muse, mutect2, varscan2
- PHF12 | c.142C>T p.R48W | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99255788; called by muse, mutect2, varscan2
- PPM1K | c.859C>T p.H287Y | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV99901076; called by muse, mutect2, varscan2
- PRPF8 | c.58C>A p.P20T | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV100517480; called by muse, mutect2
- RYR3 | c.11716G>C p.E3906Q (on ENST00000389232; = p.E3907Q on NM_001036.6) | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.661); catalogued as COSV101213204; called by muse, mutect2, varscan2
- SAFB | c.1347C>A p.Y449* | Nonsense Mutation (SNP) | VAF 6/30 reads (20%) | catalogued as COSV99412994; called by muse, mutect2, varscan2
- SERPINA4 | c.1145G>C p.S382T | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0.034); catalogued as COSV100097332; called by muse, mutect2, varscan2
- SKA3 | c.1015G>C p.E339Q | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.066); catalogued as COSV53437744; called by muse, mutect2, varscan2
- SLC22A2 | c.461C>T p.S154L | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.12); catalogued as COSV100871012; called by muse, mutect2, varscan2
- SLC25A48 | c.298C>T p.P100S | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as COSV50849062; called by muse, mutect2
- SUN5 | c.203G>T p.G68V | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.203); catalogued as COSV100644861; called by muse, mutect2, varscan2
- TMEM260 | c.690G>T p.L230F | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV99840504; called by muse, mutect2, varscan2
- UGCG | c.272A>C p.D91A | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.218); catalogued as COSV100958971; called by muse, mutect2, varscan2
- USP6NL | c.448C>T p.R150C | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs200462539, COSV99509878; called by muse, mutect2, varscan2
- ZNF292 | c.3904G>A p.E1302K | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.156); catalogued as COSV100370724, COSV60535062; called by muse, mutect2, varscan2
- ZNF534 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV56515327, COSV99989960; called by muse, mutect2
- ZNFX1 | c.5010G>T p.R1670S | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV100872471; called by muse, mutect2, varscan2
- CDC27 | c.1258C>T p.Q420* | Nonsense Mutation (SNP) | VAF 7/56 reads (13%) | called by muse, mutect2
- COL12A1 | c.1455C>A p.S485R | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DMXL1 | c.8275+1del p.X2759_splice | Splice Site (DEL) | VAF 4/39 reads (10%) | called by mutect2, pindel, varscan2
- NDUFS6 | c.330_340del p.T111Lfs*24 | Frame Shift Del (DEL) | VAF 17/47 reads (36%) | called by mutect2, pindel, varscan2
- ACAP2 | c.1617G>A p.L539= | Silent (SNP) | VAF 38/72 reads (53%) | catalogued as rs895712477, COSV100462471; called by muse, mutect2, varscan2
- AGFG2 | c.1350G>T p.L450= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV99499422; called by muse, mutect2, varscan2
- C1GALT1C1 | c.300C>T p.F100= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as rs1485985388, COSV58974764; called by muse, mutect2, varscan2
- CCDC85A | c.984C>T p.H328= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs766118772, COSV68152936; called by muse, mutect2, varscan2
- CDH6 | c.732G>A p.Q244= | Silent (SNP) | VAF 35/101 reads (35%) | catalogued as rs1014398832, COSV99419965; called by muse, mutect2, varscan2
- GPR158 | c.669C>T p.F223= | Silent (SNP) | VAF 5/49 reads (10%) | catalogued as COSV100893967, COSV99059276; called by mutect2, varscan2
- HOXB6 | c.516G>T p.T172= | Silent (SNP) | VAF 9/79 reads (11%) | catalogued as COSV53314346, COSV99494631; called by muse, mutect2, varscan2
- KLHL36 | c.717C>T p.L239= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs1428135346, COSV99256937; called by muse, mutect2
- MYO1C | c.1551C>T p.V517= (on ENST00000648651 / NM_001080779.2; = p.V482= on NM_033375.5) | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as COSV100704464; called by muse, mutect2, varscan2
- NACC2 | c.205C>T p.L69= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as rs1157438245; called by muse, mutect2, varscan2
- PCDH15 | c.42G>A p.G14= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as COSV100223942; called by muse, mutect2, varscan2
- SHARPIN | c.531G>A p.G177= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as COSV100010506; called by muse, mutect2, varscan2
- SLC43A1 | c.123G>A p.K41= | Silent (SNP) | VAF 22/100 reads (22%) | catalogued as COSV99561106; called by muse, mutect2, varscan2
- SNRNP40 | c.117G>T p.A39= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as COSV99745503; called by muse, mutect2, varscan2
- SNX29 | c.1752C>G p.L584= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as COSV100029414; called by muse, mutect2, varscan2
- SOX9 | c.438G>A p.L146= | Silent (SNP) | VAF 15/99 reads (15%) | catalogued as rs1443148013, COSV55428662, COSV99818574; called by muse, mutect2, varscan2
- TNFAIP2 | c.1707C>T p.S569= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV60695503; called by muse, mutect2, varscan2
- TRPM4 | c.3477G>A p.L1159= | Silent (SNP) | VAF 13/88 reads (15%) | catalogued as COSV99420407; called by muse, mutect2, varscan2
- ZNF543 | c.741C>T p.I247= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV100386842; called by mutect2, varscan2
- KLK2 | c.630+10C>T | Intron (SNP) | VAF 14/94 reads (15%) | catalogued as COSV57568690; called by muse, mutect2, varscan2
